TCGA case TCGA-VP-A878 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/48f36fbe-356a-40af-b81f-8ea0b1369bab

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 58.6 years (21,402 days); Year of diagnosis: 2006; Method of diagnosis: Core Biopsy; AJCC clinical T: T1c; AJCC pathologic T: T2c; AJCC pathologic N: N1; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 5; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Gleason score: 9.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 3; Tumor level prostate: Apex / Base; Zone of origin prostate: Overlapping/multiple zones.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Goserelin Acetate; Days to treatment start: 115 days; Days to treatment end: 784 days (2.1 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Leuprolide Acetate; Days to treatment start: 2,376 days (6.5 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Biochemical Recurrence.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Bone, NOS. Age at diagnosis: 65.0 years (23,756 days); Days to diagnosis: 2,354 days (6.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (9 entries)
- Day 35 (initial diagnosis): Days to imaging: 35 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 44 (initial diagnosis): Days to imaging: 44 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: Extraprostatic Extension, Regional Lymphadenopathy.
- Day 98 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 98 days.
- Days to follow up: 1,843 days (5.0 years); Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 1,843 days (5.0 years).
- Days to follow up: 1,934 days (5.3 years); Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 1,934 days (5.3 years).
- Days to follow up: 2,011 days (5.5 years); Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 2,011 days (5.5 years).
- Day 2,354 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 2,354 days (6.4 years).
- Days to follow up: 3,130 days (8.6 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 2,704.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.1 ng/mL (day 2,704).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VP-A878-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-VP-A878-01A-03-TSC: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VP-A878-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VP-A878-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: No; Lymph nodes examined: Yes; Biochemical recurrence indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Base.
- Diagnostic ct abd pelvis results: Ct scan ab pelvis results: Extraprostatic Extension (regional lymphadenopathy)[e.g. cN1].
- Stage record, Psa: PSA most recent results: 0.1.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 5.
- Drug treatment 1: Pharmaceutical therapy drug name: Lupron.
- Drug treatment 2: Pharmaceutical therapy drug name: Zoladex.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event type: Distant Metastasis; New tumor event site: Bone; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Progression after hormone treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,130 days; disease-specific survival: no event (censored), 3,130 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 98 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VP-A878-01A-31D-A34T-01): tumor purity 0.41, ploidy 1.93, whole-genome doublings 0.
